Somatic mutation profile of tumor specimen ALCH-AEPF-TTP1-A (aliquot ALCH-AEPF-TTP1-A-3-0-D-A667-36) from ALCHEMIST case ALCH-AEPF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.8 years (26,602 days).
Specimen ALCH-AEPF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e23ae6e8-cde2-47e9-9194-5695348f8ad1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEPF-NB1-A (Blood Derived Normal), aliquot ALCH-AEPF-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b47482f0-0267-481b-9c4d-c6b5dac95d88

The open-access MAF lists 314 somatic variants for this specimen: 226 protein-altering or splice-affecting, 51 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 194, Silent 51, Intron 15, Nonsense Mutation 12, Frame Shift Del 9, RNA 8, 5'UTR 6, Splice Site 5, 5'Flank 5, Frame Shift Ins 3, Splice Region 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 102/495 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 38/228 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SF3B1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 79/475 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.4960C>T p.R1654C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs374991540; called by muse, mutect2, varscan2
- AKAP7 | c.610C>G p.Q204E | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs1481618535; called by muse, mutect2, varscan2
- ATP10D | c.670G>T p.V224F | Missense Mutation (SNP) | VAF 62/341 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV56705428; called by muse, mutect2, varscan2
- ATP11A | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs773276133; called by muse, mutect2
- CACNA1E | c.3226G>T p.D1076Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.83); catalogued as COSV62426448; called by muse, mutect2, varscan2
- CACNA1I | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756481754; called by muse, mutect2
- CDH9 | c.1727C>A p.P576Q | Missense Mutation (SNP) | VAF 66/534 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50293167; called by muse, mutect2, varscan2
- CLC | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 71/361 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV55685110; called by muse, mutect2, varscan2
- COL11A1 | c.2699C>A p.P900H | Missense Mutation (SNP) | VAF 106/660 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62185221, COSV62192647; called by muse, mutect2, varscan2
- COL3A1 | c.1207A>G p.I403V | Missense Mutation (SNP) | VAF 115/642 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.28); catalogued as rs1372036761; called by muse, mutect2, varscan2
- COL5A1 | c.2843G>T p.R948L | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV65677219; called by muse, mutect2, varscan2
- CUL4B | c.348G>T p.Q116H | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs755306871, COSV60686305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF12L1 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64421266; called by muse, mutect2, varscan2
- DIS3L2 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV99807643; called by muse, mutect2, varscan2
- EDNRB | c.699G>T p.L233F (on ENST00000377211 / NM_001201397.1; = p.L143F on NM_000115.5) | Missense Mutation (SNP) | VAF 52/363 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57524311; called by muse, mutect2, varscan2
- ENPP2 | c.1069G>T p.V357F (on ENST00000075322 / NM_001040092.3; = p.V409F on NM_006209.5) | Missense Mutation (SNP) | VAF 69/372 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569287310; called by muse, mutect2, varscan2
- ERICH3 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 96/527 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100443914; called by muse, mutect2, varscan2
- FAM135B | c.2482C>A p.P828T | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.011); catalogued as COSV52737981, COSV52741345; called by muse, mutect2, varscan2
- FAM83B | c.1340G>T p.R447L | Missense Mutation (SNP) | VAF 89/465 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.389); catalogued as rs573151626; called by muse, mutect2, varscan2
- FAT3 | c.12005G>T p.R4002L | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV53129249; called by muse, mutect2, varscan2
- FBXO40 | c.1357G>T p.G453W | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV100573072, COSV57524870; called by muse, mutect2, varscan2
- GABRB3 | c.1175C>A p.A392E | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.062); catalogued as COSV54671024; called by muse, mutect2, varscan2
- HEATR1 | c.476G>T p.R159I | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100857227; called by muse, mutect2, varscan2
- HOXA3 | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 15/107 reads (14%) | catalogued as COSV57829517; called by muse, mutect2, varscan2
- IFITM5 | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1320606925; called by muse, mutect2, varscan2
- IFNA5 | c.569G>T p.*190Lext*11 | Nonstop Mutation (SNP) | VAF 31/159 reads (19%) | catalogued as COSV99423781; called by muse, mutect2, varscan2
- IL1RL2 | c.393G>C p.E131D | Missense Mutation (SNP) | VAF 80/469 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.105); catalogued as COSV99961117; called by muse, mutect2, varscan2
- ITIH6 | c.1463C>A p.A488D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99513409; called by muse, mutect2, varscan2
- KCNJ11 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV100379098; called by muse, mutect2, varscan2
- KIF19 | c.1576C>A p.R526S | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.011); catalogued as rs201212996, COSV63429548; called by muse, mutect2, varscan2
- KRT39 | c.739del p.E247Rfs*7 | Frame Shift Del (DEL) | VAF 44/212 reads (21%) | catalogued as COSV100842220; called by mutect2, pindel, varscan2
- KRTAP20-2 | c.15C>A p.S5R | Missense Mutation (SNP) | VAF 33/165 reads (20%) | PolyPhen possibly damaging (0.602); catalogued as COSV58183635; called by muse, mutect2, varscan2
- LAMA5 | c.6923C>T p.S2308L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); catalogued as rs1167220383; called by muse, mutect2, varscan2
- LOXHD1 | c.5713G>A p.V1905M (on ENST00000642948; = p.V1843M on NM_144612.7) | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1406257799, COSV100192113; called by muse, mutect2, varscan2
- LOXHD1 | c.2805G>T p.K935N | Missense Mutation (SNP) | VAF 72/504 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1438762609; called by muse, mutect2, varscan2
- LRP1B | c.13046C>A p.T4349K | Missense Mutation (SNP) | VAF 102/610 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV101253137; called by muse, mutect2, varscan2
- MAGEB18 | c.43C>A p.R15S | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57463629, COSV57465017; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.92); catalogued as COSV99151189; called by muse, mutect2, varscan2
- MME | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 144/822 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100852579; called by muse, varscan2
- NALCN | c.1372G>T p.V458L | Missense Mutation (SNP) | VAF 89/524 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as COSV51963359; called by muse, mutect2, varscan2
- NAV3 | c.3496G>T p.V1166F | Missense Mutation (SNP) | VAF 128/371 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); catalogued as COSV57088033; called by muse, varscan2
- NBAS | c.3362T>C p.I1121T | Missense Mutation (SNP) | VAF 58/458 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs772573001; called by muse, mutect2
- NEO1 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as rs1378815636; called by muse, mutect2, varscan2
- NIPAL4 | c.674T>A p.V225E | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs1295111912; called by muse, mutect2, varscan2
- NLRP4 | c.479del p.G160Efs*6 | Frame Shift Del (DEL) | VAF 47/272 reads (17%) | catalogued as COSV56721783; called by mutect2, pindel, varscan2
- OR2L5 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 115/560 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs1307773858; called by muse, mutect2, varscan2
- OR5AC2 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 55/350 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV62279154; called by muse, mutect2, varscan2
- PADI1 | c.606C>G p.N202K | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1319925876, COSV64937855; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.290C>T p.A97V (on ENST00000259318 / NM_001136562.3; = p.A328V on NM_007203.5) | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs147894013; called by muse, mutect2, varscan2
- PCDH8 | c.2631G>A p.E877= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as rs754005347; called by muse, varscan2
- PCDHGB1 | c.1552del p.H518Tfs*25 | Frame Shift Del (DEL) | VAF 24/171 reads (14%) | catalogued as COSV99545315; called by mutect2, pindel, varscan2
- PCLO | c.14690G>C p.R4897P | Missense Mutation (SNP) | VAF 94/629 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61616504; called by muse, varscan2
- PCLO | c.14689C>T p.R4897C | Missense Mutation (SNP) | VAF 101/645 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429073; called by muse, mutect2, varscan2
- PHF3 | c.5560C>T p.P1854S | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV50339939; called by muse, mutect2, varscan2
- PLA2G6 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100140161; called by muse, mutect2, varscan2
- PPP4R1 | c.178A>G p.I60V (on ENST00000400556 / NM_001042388.3; = p.I43V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs748123208; called by muse, mutect2, varscan2
- PXDNL | c.3885G>C p.W1295C | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100682869; called by muse, mutect2, varscan2
- RGS6 | c.1390C>A p.R464S | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs368125974, COSV59563439; called by muse, mutect2, varscan2
- RSPO1 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as COSV62973877; called by muse, mutect2, varscan2
- SERPINE3 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68544957; called by muse, mutect2, varscan2
- SETBP1 | c.4373G>T p.R1458M | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56314381; called by muse, mutect2, varscan2
- SPANXN2 | c.117G>C p.Q39H | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.979); catalogued as COSV65129427; called by muse, varscan2
- TAS1R3 | c.2284C>A p.R762S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750240840; called by muse, mutect2, varscan2
- TENM1 | c.5170G>T p.G1724C | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV64429110; called by muse, mutect2
- TICAM1 | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1191480606; called by muse, mutect2
- TRAPPC12 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 40/216 reads (19%) | catalogued as COSV100161097; called by muse, mutect2, varscan2
- TRO | c.2387G>T p.G796V | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV51506387; called by muse, mutect2, varscan2
- TRPA1 | c.2887G>A p.D963N | Missense Mutation (SNP) | VAF 102/716 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867812306; called by muse, mutect2, varscan2
- TSPAN8 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 70/402 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs774338946, COSV56080730; called by muse, varscan2
- VCAN | c.7575G>T p.R2525S | Missense Mutation (SNP) | VAF 107/645 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99426878; called by muse, mutect2, varscan2
- WDR87 | c.7712A>G p.E2571G | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs1003341073; called by muse, mutect2, varscan2
- WFIKKN2 | c.1253G>A p.G418D | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60957816; called by muse, mutect2, varscan2
- ZNF229 | c.1745G>T p.R582L | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as COSV52159248; called by muse, mutect2
- ZNF474 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 41/225 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99681987; called by muse, mutect2, varscan2
- ABCC11 | c.3477C>A p.H1159Q | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by mutect2, varscan2
- ADAMTS2 | c.2287C>A p.L763M | Missense Mutation (SNP) | VAF 76/372 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ADGRA2 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- ADGRD2 | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ADGRL3 | c.4543C>A p.P1515T (on ENST00000506720 / NM_001322402.2; = p.P1404T on NM_015236.6) | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ALB | c.1453T>C p.C485R | Missense Mutation (SNP) | VAF 61/559 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALPK2 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 91/501 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- AMER1 | c.2661G>T p.M887I | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMER1 | c.1391C>G p.A464G | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); called by muse, mutect2
- ANGPTL6 | c.723del p.M242Cfs*41 | Frame Shift Del (DEL) | VAF 36/227 reads (16%) | called by mutect2, pindel, varscan2
- ANKRD30B | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.238); called by muse, varscan2
- AR | c.1717G>T p.G573* | Nonsense Mutation (SNP) | VAF 94/474 reads (20%) | called by mutect2, varscan2
- ARHGAP6 | c.976del p.E326Nfs*53 | Frame Shift Del (DEL) | VAF 68/414 reads (16%) | called by mutect2, pindel, varscan2
- ARRDC3 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 44/315 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ASAP2 | c.2446A>T p.S816C | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ATF7IP | c.1143dup p.G382Wfs*7 | Frame Shift Ins (INS) | VAF 45/225 reads (20%) | called by mutect2, pindel, varscan2
- BANK1 | c.1154T>C p.I385T | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- BFSP2 | c.451G>C p.G151R | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2
- BRAF | c.143G>T p.W48L | Missense Mutation (SNP) | VAF 98/510 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.46); called by mutect2, varscan2
- C3orf70 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CALU | c.716A>G p.E239G | Missense Mutation (SNP) | VAF 100/585 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CASP8AP2 | c.2663-1G>T p.X888_splice | Splice Site (SNP) | VAF 24/91 reads (26%) | called by muse, varscan2
- CCAR1 | c.2566A>T p.K856* | Nonsense Mutation (SNP) | VAF 63/345 reads (18%) | called by muse, mutect2, varscan2
- CCNF | c.2120C>G p.T707S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD1D | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD300LD | c.512T>A p.L171H | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CDH9 | c.1726C>A p.P576T | Missense Mutation (SNP) | VAF 65/533 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP65 | c.924G>T p.Q308H | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CLCN1 | c.2685G>C p.K895N | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLCN3 | c.546A>T p.E182D | Missense Mutation (SNP) | VAF 67/343 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A6 | c.1892G>T p.G631V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A3 | c.3518C>T p.T1173I | Missense Mutation (SNP) | VAF 35/295 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CYLC1 | c.18-1G>A p.X6_splice | Splice Site (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- DCDC1 | c.2183T>A p.V728D | Missense Mutation (SNP) | VAF 72/413 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- DDX60 | c.5096A>T p.E1699V | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); called by muse, varscan2
- DLG3 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- DMD | c.9505G>T p.V3169F | Missense Mutation (SNP) | VAF 139/862 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDA2R | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- EDAR | c.921C>A p.H307Q | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ELAVL3 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ENPP1 | c.2001G>T p.K667N | Missense Mutation (SNP) | VAF 88/459 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EP400 | c.1009_1025del p.T337Gfs*47 | Frame Shift Del (DEL) | VAF 22/194 reads (11%) | called by mutect2, varscan2
- EPS8L2 | c.1489G>T p.V497F | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ESCO1 | c.95A>T p.Q32L | Missense Mutation (SNP) | VAF 64/429 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FMO3 | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- FNIP2 | c.656-4T>A | Splice Region (SNP) | VAF 56/320 reads (18%) | called by muse, mutect2, varscan2
- GAPVD1 | c.3812-1G>A p.X1271_splice (on ENST00000394104; = p.X1280_splice on NM_015635.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 28/170 reads (16%) | called by muse, mutect2
- GCAT | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GLDC | c.1873G>T p.G625* | Nonsense Mutation (SNP) | VAF 82/608 reads (13%) | called by muse, mutect2, varscan2
- GOLGA3 | c.1013C>G p.T338R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR26 | c.988C>A p.Q330K | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRIA3 | c.2269_2270del p.G757Kfs*13 | Frame Shift Del (DEL) | VAF 86/498 reads (17%) | called by mutect2, pindel*, varscan2*
- GRIK1 | c.1406T>C p.L469P | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIP1 | c.3019T>A p.L1007M (on ENST00000359742 / NM_001379345.1; = p.L955M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/622 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- GSDMB | c.585G>T p.R195S | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- HCRTR2 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 62/378 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.03); called by mutect2, varscan2
- HIPK2 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 90/460 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPCL2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HNRNPUL1 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXC13 | c.830del p.K277Rfs*28 | Frame Shift Del (DEL) | VAF 47/309 reads (15%) | called by mutect2, pindel, varscan2
- HSPA2 | c.1870G>T p.G624C | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by mutect2, varscan2
- HYDIN | c.1301A>T p.Q434L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by mutect2, varscan2
- INTS4 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITGAD | c.1748T>C p.F583S | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KBTBD11 | c.1265T>A p.L422Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH3 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- KCNH7 | c.2570C>G p.T857R | Missense Mutation (SNP) | VAF 83/460 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KCNH8 | c.383C>A p.A128D | Missense Mutation (SNP) | VAF 73/602 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- KIF26A | c.2587G>T p.G863C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.436); called by mutect2, varscan2
- KIRREL1 | c.1401G>T p.Q467H | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KLF17 | c.672dup p.A225Sfs*2 | Frame Shift Ins (INS) | VAF 27/150 reads (18%) | called by mutect2, pindel, varscan2
- KRT3 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- KRT83 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 63/321 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LHX2 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- LILRA2 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LLGL2 | c.436C>A p.L146M | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- LMO7 | c.430C>G p.Q144E (on ENST00000357063; = p.Q159E on NM_005358.5) | Missense Mutation (SNP) | VAF 62/390 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- LRP1B | c.13679C>A p.P4560Q | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEB1 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAP1B | c.5437A>G p.T1813A | Missense Mutation (SNP) | VAF 11/320 reads (3%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- MED26 | c.1763A>T p.D588V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, varscan2
- MGAT4C | c.931C>A p.H311N | Missense Mutation (SNP) | VAF 88/519 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MKRN3 | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 66/396 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MPC1L | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.878); called by muse, varscan2
- NADSYN1 | c.1621G>T p.G541W | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBEAL1 | c.4973C>G p.P1658R | Missense Mutation (SNP) | VAF 95/555 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBPF4 | c.77C>A p.S26* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | called by mutect2, varscan2
- NFATC4 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFKB1 | c.2779A>T p.S927C (on ENST00000394820 / NM_001382627.1; = p.S928C on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- NGDN | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 70/458 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NHSL1 | c.3271G>T p.A1091S | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- NLK | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 70/544 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.689); called by muse, varscan2
- NOTCH3 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- NRAP | c.1799C>A p.S600Y (on ENST00000359988 / NM_001322945.2; = p.S565Y on NM_006175.4) | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by mutect2, varscan2
- NUP155 | c.2857G>T p.G953* (on ENST00000231498 / NM_153485.3; = p.G894* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 92/538 reads (17%) | called by mutect2, varscan2
- OR4P4 | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- OR8G2P | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 63/372 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); called by muse, varscan2
- PAX1 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDH11X | c.439T>A p.S147T | Missense Mutation (SNP) | VAF 105/559 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCID2 | c.742A>C p.K248Q | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PCNX2 | c.1556G>C p.C519S | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PIK3R5 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLXNA3 | c.2771C>A p.T924K | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- POLR2B | c.828A>T p.L276F | Missense Mutation (SNP) | VAF 84/491 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POPDC2 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- POU2F1 | c.463G>T p.A155S (on ENST00000541643 / NM_001365848.1; = p.A178S on NM_002697.4) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PPP1R9B | c.2399A>C p.K800T | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PRSS12 | c.1917-1G>T p.X639_splice | Splice Site (SNP) | VAF 54/504 reads (11%) | called by mutect2, varscan2
- PRUNE2 | c.7899G>T p.W2633C | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PSMB2 | c.99C>A p.D33E | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAPGEF2 | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- RNF31 | c.2480G>T p.R827L | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- S1PR1 | c.459_460insA p.G154Rfs*4 | Frame Shift Ins (INS) | VAF 35/212 reads (17%) | called by mutect2, pindel, varscan2
- SAGE1 | c.2005+1G>T p.X669_splice | Splice Site (SNP) | VAF 27/142 reads (19%) | called by muse, mutect2, varscan2
- SAMD3 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SIGLEC12 | c.1552del p.D518Ifs*19 (on ENST00000291707 / NM_053003.4; = p.D400Ifs*19 on NM_033329.2) | Frame Shift Del (DEL) | VAF 47/311 reads (15%) | called by mutect2, varscan2
- SLC25A33 | c.158A>T p.Q53L | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- SLC7A14 | c.1616C>G p.P539R | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SLITRK5 | c.825G>C p.L275F | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SNX10 | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 62/501 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPAG16 | c.914G>T p.C305F | Missense Mutation (SNP) | VAF 56/318 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA5 | c.622A>T p.S208C | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- STYXL2 | c.2665A>T p.T889S | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TAF2 | c.3519T>G p.S1173R | Missense Mutation (SNP) | VAF 108/648 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- TAF7L | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- TBX21 | c.1500G>C p.R500S | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TCF4 | c.1010C>A p.T337N | Missense Mutation (SNP) | VAF 98/652 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.018); called by mutect2, varscan2
- TGM6 | c.1813G>T p.E605* | Nonsense Mutation (SNP) | VAF 60/433 reads (14%) | called by muse, mutect2, varscan2
- TMC3 | c.169C>A p.Q57K | Missense Mutation (SNP) | VAF 58/359 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- TMEFF1 | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 54/378 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, varscan2
- TMPRSS11B | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TNRC6A | c.1826G>A p.G609D | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- TOP3A | c.1356G>C p.Q452H | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- TOP3B | c.1787T>C p.F596S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TRO | c.2386G>A p.G796S | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TUBGCP6 | c.1767G>T p.K589N | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- UBQLN3 | c.1520T>G p.L507R | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- VEGFC | c.640A>G p.K214E | Missense Mutation (SNP) | VAF 66/511 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- WFS1 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 59/289 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XKR4 | c.1315A>T p.I439F | Missense Mutation (SNP) | VAF 77/381 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- YTHDF3 | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 86/461 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ZIC4 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 55/240 reads (23%) | called by muse, mutect2, varscan2
- ZNF208 | c.3375C>G p.F1125L | Missense Mutation (SNP) | VAF 112/637 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF292 | c.1564A>C p.K522Q | Missense Mutation (SNP) | VAF 119/723 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF426 | c.329G>T p.W110L | Missense Mutation (SNP) | VAF 67/371 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ZNF536 | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF729 | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 77/462 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF750 | c.1691C>A p.P564Q | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.027); called by muse, mutect2
- ZNF93 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 95/529 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCB10 | c.1164A>T p.A388= | Silent (SNP) | VAF 76/419 reads (18%) | called by muse, mutect2, varscan2
- ADGRV1 | c.11673G>T p.V3891= | Silent (SNP) | VAF 56/428 reads (13%) | called by muse, mutect2
- ARHGAP6 | c.468C>G p.L156= | Silent (SNP) | VAF 31/191 reads (16%) | called by muse, mutect2, varscan2
- BTBD11 | c.2277T>C p.S759= (on ENST00000280758 / NM_001018072.2; = p.S296= on NM_001017523.2) | Silent (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- CFAP251 | c.3057A>G p.G1019= | Silent (SNP) | VAF 8/177 reads (5%) | called by muse, mutect2
- CHST8 | c.1134G>T p.S378= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as rs1414974292, COSV52861714; called by muse, mutect2, varscan2
- COL17A1 | c.1419C>A p.L473= | Silent (SNP) | VAF 28/163 reads (17%) | catalogued as COSV62229902; called by muse, mutect2, varscan2
- CRACD | c.720G>T p.A240= | Silent (SNP) | VAF 42/236 reads (18%) | catalogued as rs758326958, COSV51731084; called by muse, mutect2, varscan2
- DCHS1 | c.8355G>T p.V2785= | Silent (SNP) | VAF 26/138 reads (19%) | called by muse, mutect2, varscan2
- DHX30 | c.105A>T p.P35= | Silent (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- DIS3L2 | c.39G>A p.L13= | Silent (SNP) | VAF 45/292 reads (15%) | called by muse, mutect2, varscan2
- DYRK2 | c.168G>A p.R56= | Silent (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- EMID1 | c.582C>T p.L194= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100469225; called by muse, mutect2
- ESRRG | c.456C>T p.F152= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV63166549; called by muse, mutect2, varscan2
- FBXL7 | c.415C>A p.R139= | Silent (SNP) | VAF 22/154 reads (14%) | catalogued as COSV100309584; called by muse, mutect2, varscan2
- GABRA1 | c.783C>T p.C261= | Silent (SNP) | VAF 128/698 reads (18%) | called by muse, mutect2, varscan2
- GABRA2 | c.927T>C p.Y309= | Silent (SNP) | VAF 76/553 reads (14%) | called by muse, mutect2, varscan2
- GABRA5 | c.1221C>A p.P407= | Silent (SNP) | VAF 110/620 reads (18%) | catalogued as COSV100165913; called by muse, varscan2
- GPAT2 | c.2017C>A p.R673= | Silent (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- GPR143 | c.40C>A p.R14= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV66633299; called by muse, mutect2, varscan2
- HCRTR2 | c.687G>T p.L229= | Silent (SNP) | VAF 62/382 reads (16%) | called by mutect2, varscan2
- HGF | c.504G>T p.R168= | Silent (SNP) | VAF 90/478 reads (19%) | called by muse, mutect2, varscan2
- HUWE1 | c.1746A>C p.T582= | Silent (SNP) | VAF 80/552 reads (14%) | called by muse, mutect2, varscan2
- IQSEC2 | c.1624C>A p.R542= (on ENST00000642864 / NM_001111125.3; = p.R337= on NM_015075.2) | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV64727273; called by muse, mutect2, varscan2
- IRX3 | c.1137G>A p.A379= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100315363; called by muse, mutect2
- KCNQ2 | c.1678C>A p.R560= (on ENST00000359125 / NM_172107.4; = p.R532= on NM_004518.6) | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs773171451, CM120574; called by muse, mutect2, varscan2
- KHDC3L | c.354A>T p.S118= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2
- LAMA4 | c.4389T>C p.P1463= (on ENST00000230538 / NM_001105206.3; = p.P1456= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/539 reads (15%) | catalogued as rs782791838; called by muse, mutect2, varscan2
- MAMLD1 | c.1779C>A p.T593= | Silent (SNP) | VAF 26/132 reads (20%) | called by muse, varscan2
- NAV2 | c.4233C>G p.A1411= (on ENST00000396087 / NM_001244963.2; = p.A1388= on NM_145117.5) | Silent (SNP) | VAF 30/170 reads (18%) | called by muse, mutect2, varscan2
- NAV3 | c.5877T>C p.R1959= (on ENST00000397909 / NM_001024383.2; = p.R1937= on NM_014903.6) | Silent (SNP) | VAF 67/354 reads (19%) | called by muse, mutect2, varscan2
- NLRP13 | c.546G>A p.E182= | Silent (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2
- NLRP8 | c.141C>T p.N47= | Silent (SNP) | VAF 53/275 reads (19%) | catalogued as rs576296836, COSV52592535; called by muse, mutect2, varscan2
- NTRK2 | c.156C>A p.I52= | Silent (SNP) | VAF 96/492 reads (20%) | catalogued as COSV52865746; called by muse, varscan2
- OPRD1 | c.741G>T p.S247= | Silent (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- OR1L1 | c.708A>G p.K236= (on ENST00000373686; = p.K186= on NM_001005236.3) | Silent (SNP) | VAF 45/226 reads (20%) | called by muse, mutect2, varscan2
- OR7G2 | c.732C>T p.S244= | Silent (SNP) | VAF 76/424 reads (18%) | called by muse, mutect2, varscan2
- PREX1 | c.3813G>T p.R1271= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as COSV64256104; called by muse, varscan2
- PROX1 | c.489A>G p.R163= | Silent (SNP) | VAF 34/221 reads (15%) | called by muse, mutect2, varscan2
- PXDNL | c.2034G>A p.Q678= | Silent (SNP) | VAF 4/46 reads (9%) | called by mutect2, varscan2
- RMC1 | c.1443C>T p.A481= | Silent (SNP) | VAF 82/502 reads (16%) | catalogued as rs768318483, COSV52574138; called by muse, varscan2
- ROBO4 | c.1977G>A p.L659= | Silent (SNP) | VAF 25/105 reads (24%) | called by muse, mutect2, varscan2
- RTL1 | c.2292C>T p.S764= | Silent (SNP) | VAF 25/124 reads (20%) | called by muse, mutect2, varscan2
- SCN10A | c.2178G>A p.Q726= | Silent (SNP) | VAF 38/293 reads (13%) | called by muse, varscan2
- SEMA3D | c.555C>T p.F185= | Silent (SNP) | VAF 72/438 reads (16%) | catalogued as rs750300091, COSV52390584, COSV52397941; called by muse, mutect2, varscan2
- SHKBP1 | c.504T>C p.L168= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- SMO | c.1215G>T p.L405= | Silent (SNP) | VAF 27/168 reads (16%) | catalogued as rs1381722558; called by muse, mutect2, varscan2
- TGIF2LX | c.186T>A p.V62= | Silent (SNP) | VAF 59/322 reads (18%) | called by muse, mutect2, varscan2
- TRBV20-1 | c.118C>T p.L40= | Silent (SNP) | VAF 67/290 reads (23%) | catalogued as rs1461053492; called by muse, mutect2, varscan2
- ULK2 | c.2688G>T p.A896= | Silent (SNP) | VAF 53/286 reads (19%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.1254C>A p.G418= | Silent (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- ABCG2 | c.-268C>A | 5'UTR (SNP) | VAF 33/245 reads (13%) | called by muse, mutect2, varscan2
- AC018638.4 | n.335G>A | RNA (SNP) | VAF 68/408 reads (17%) | catalogued as rs1464213819; called by muse, mutect2, varscan2
- AC068633.1 | n.179G>C | RNA (SNP) | VAF 60/424 reads (14%) | called by muse, mutect2, varscan2
- ACTN2 | c.-1C>G | 5'UTR (SNP) | VAF 25/172 reads (15%) | called by muse, mutect2, varscan2
- ADCYAP1 | chr18:904510 G>T | 5'Flank (SNP) | VAF 36/211 reads (17%) | called by muse, mutect2, varscan2
- ADCYAP1 | chr18:904511 G>T | 5'Flank (SNP) | VAF 34/207 reads (16%) | called by muse, mutect2, varscan2
- ALDH7A1 | c.1416-20A>G | Intron (SNP) | VAF 88/500 reads (18%) | catalogued as rs1331412786; called by muse, mutect2, varscan2
- CAMK2G | c.1273+740A>T | Intron (SNP) | VAF 39/169 reads (23%) | called by muse, mutect2, varscan2
- CCDC88A | c.273+42T>A | Intron (SNP) | VAF 66/352 reads (19%) | called by muse, mutect2, varscan2
- CNTNAP3P2 | n.377A>T | RNA (SNP) | VAF 28/256 reads (11%) | called by muse, mutect2, varscan2
- DDC | c.944+2372G>A | Intron (SNP) | VAF 53/342 reads (15%) | called by muse, mutect2, varscan2
- DKK2 | c.529+22G>T | Intron (SNP) | VAF 26/182 reads (14%) | called by muse, varscan2
- DNM2 | c.162-40G>A | Intron (SNP) | VAF 32/166 reads (19%) | catalogued as rs199874824; called by muse, mutect2, varscan2
- FAM78A | c.323+5448A>T | Intron (SNP) | VAF 52/376 reads (14%) | catalogued as COSV64843112; called by muse, mutect2, varscan2
- HAND2-AS1 | n.512+1263C>A | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- HCK | c.63-1917A>G | Intron (SNP) | VAF 76/422 reads (18%) | called by muse, mutect2, varscan2
- IGHEP1 | n.557A>T | RNA (SNP) | VAF 20/170 reads (12%) | called by muse, mutect2
- LINC02869 | n.314T>C | RNA (SNP) | VAF 53/301 reads (18%) | called by muse, mutect2, varscan2
- MFRP | chr11:119344992 C>A | 5'Flank (SNP) | VAF 28/143 reads (20%) | called by muse, mutect2, varscan2
- MIR507 | n.1G>T | RNA (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- MYH8 | c.*27G>T | 3'UTR (SNP) | VAF 58/393 reads (15%) | called by muse, mutect2, varscan2
- NEU4 | c.-4+57G>T | Intron (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- NR5A2 | c.64+1195A>G | Intron (SNP) | VAF 40/278 reads (14%) | called by muse, varscan2
- OSBPL2 | c.-5G>A | 5'UTR (SNP) | VAF 29/347 reads (8%) | called by muse, mutect2
- PBDC1 | c.-54C>T | 5'UTR (SNP) | VAF 19/119 reads (16%) | catalogued as rs1424531076; called by muse, mutect2, varscan2
- PGLYRP2 | c.1641+128G>T | Intron (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- PTGES2 | chr9:128128799 C>T | 5'Flank (SNP) | VAF 8/221 reads (4%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159379 C>A | 5'Flank (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.3095C>A | RNA (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- RPL10 | c.*32C>G | 3'UTR (SNP) | VAF 59/416 reads (14%) | catalogued as rs781882279; called by muse, mutect2, varscan2
- RPL11 | c.-25C>T | 5'UTR (SNP) | VAF 25/223 reads (11%) | called by muse, mutect2, varscan2
- SMARCA4 | c.3546+67G>T | Intron (SNP) | VAF 20/88 reads (23%) | called by mutect2, varscan2
- SNORC | c.-5C>T | 5'UTR (SNP) | VAF 23/132 reads (17%) | called by muse, mutect2, varscan2
- SNORD114-23 | chr14:100986977 A>G | 3'Flank (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2
- SPATA31C1 | n.537G>A | RNA (SNP) | VAF 40/432 reads (9%) | catalogued as rs758239462; called by muse, mutect2
- TCF7 | c.636-1318C>A | Intron (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10360+4746A>G | Intron (SNP) | VAF 111/662 reads (17%) | catalogued as COSV59971623, COSV60002689; called by muse, mutect2, varscan2
